Somatic mutation profile of tumor specimen TCGA-WW-A8ZI-01A (aliquot TCGA-WW-A8ZI-01A-11D-A377-08) from TCGA case TCGA-WW-A8ZI, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 70.1 years (25,593 days).
Specimen TCGA-WW-A8ZI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 07054c40-4fbf-428e-860f-6b359290ab78.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-WW-A8ZI-10A (Blood Derived Normal), aliquot TCGA-WW-A8ZI-10A-01D-A37A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e8dca006-40cf-4c03-beba-1a8b68268310

The open-access MAF lists 33 somatic variants for this specimen: 24 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 8, Intron 1, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AJAP1 | c.688A>G p.T230A | Missense Mutation (SNP) | VAF 23/38 reads (61%) | SIFT tolerated (0.12); PolyPhen benign (0.021); catalogued as rs747341011, COSV100981922; called by muse, mutect2, varscan2
- CDH12 | c.1244G>A p.S415N | Missense Mutation (SNP) | VAF 40/75 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs1413594161, COSV101202980; called by muse, mutect2, varscan2
- CPSF7 | c.575G>A p.R192Q (on ENST00000394888 / NM_001136040.4; = p.R235Q on NM_024811.4) | Missense Mutation (SNP) | VAF 59/125 reads (47%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV100467466, COSV61210717; called by muse, mutect2, varscan2
- CTSC | c.266A>T p.N89I | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99910843; called by muse, mutect2, varscan2
- EGF | c.425T>G p.V142G | Missense Mutation (SNP) | VAF 64/143 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0.391); catalogued as COSV99491184, COSV99491199; called by muse, mutect2, varscan2
- GRID2 | c.1315C>T p.R439C | Missense Mutation (SNP) | VAF 59/131 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs200889267, COSV56185846, COSV56207492; called by muse, mutect2, varscan2
- GRIN2B | c.3959G>A p.R1320H | Missense Mutation (SNP) | VAF 56/109 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1216861599, COSV74208400; called by muse, mutect2, varscan2
- HTR1A | c.955G>A p.A319T | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV100109193; called by muse, mutect2
- INO80B | c.403C>T p.R135W | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.265); catalogued as rs974808928, COSV99270358; called by muse, mutect2, varscan2
- KANK1 | c.3003A>C p.G1001= | Splice Region (SNP) | VAF 11/37 reads (30%) | catalogued as COSV100619981; called by muse, mutect2, varscan2
- KRT27 | c.584G>A p.R195Q | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs757452113, COSV56972575; called by muse, mutect2, varscan2
- L3MBTL4 | c.49C>T p.R17C | Missense Mutation (SNP) | VAF 22/240 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.224); catalogued as rs767272130, COSV99530083; called by muse, mutect2
- MPRIP | c.2281C>G p.L761V | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV100506004; called by muse, mutect2, varscan2
- PCNX1 | c.5491C>T p.R1831C | Missense Mutation (SNP) | VAF 50/105 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs978227206, COSV53094209; called by muse, mutect2, varscan2
- PCSK2 | c.1526C>T p.A509V | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.32); PolyPhen benign (0.073); catalogued as COSV99360200; called by muse, mutect2, varscan2
- PIEZO2 | c.6988G>A p.V2330I | Missense Mutation (SNP) | VAF 60/92 reads (65%) | SIFT tolerated (0.22); PolyPhen benign (0.146); catalogued as rs756549202, COSV53286661; called by muse, mutect2
- PPP1R14C | c.449G>A p.R150Q | Missense Mutation (SNP) | VAF 33/63 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as rs766379125, COSV100744829, COSV63173202; called by muse, mutect2, varscan2
- PSMB11 | c.52T>A p.S18T | Missense Mutation (SNP) | VAF 58/138 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0.051); catalogued as COSV101273535; called by muse, mutect2, varscan2
- RAB24 | c.547+1G>C p.X183_splice | Splice Site (SNP) | VAF 35/84 reads (42%) | catalogued as rs751104672, COSV100293675, COSV57463321; called by muse, mutect2, varscan2
- SCN10A | c.3434G>T p.C1145F | Missense Mutation (SNP) | VAF 45/106 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101479475; called by muse, mutect2, varscan2
- TAS1R2 | c.2120G>A p.R707H | Missense Mutation (SNP) | VAF 23/124 reads (19%) | SIFT tolerated (0.45); PolyPhen benign (0.04); catalogued as rs754453014, COSV64746691; called by muse, mutect2, varscan2
- THSD7B | c.4010G>A p.G1337D (on ENST00000272643; = p.G1335D on NM_001316349.2) | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV99755024; called by muse, mutect2, varscan2
- TLR8 | c.2351G>A p.R784Q (on ENST00000218032 / NM_138636.5; = p.R802Q on NM_016610.4) | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.801); catalogued as rs761742368, COSV54316205; called by muse, mutect2, varscan2
- TWF1 | c.858A>T p.Q286H | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.157); catalogued as COSV100286161; called by muse, mutect2, varscan2
- ATP13A3 | c.3300T>C p.P1100= | Silent (SNP) | VAF 23/74 reads (31%) | catalogued as COSV99757406; called by muse, mutect2, varscan2
- CDK5RAP3 | c.840G>A p.G280= | Silent (SNP) | VAF 37/47 reads (79%) | catalogued as rs960149432, COSV58114839; called by muse, mutect2, varscan2
- EEF1AKNMT | c.1527C>T p.L509= (on ENST00000361735 / NM_015935.5; = p.L423= on NM_014955.3) | Silent (SNP) | VAF 52/134 reads (39%) | catalogued as rs1327619886, COSV100675965; called by muse, mutect2, varscan2
- FNDC1 | c.1845G>A p.S615= | Silent (SNP) | VAF 27/76 reads (36%) | catalogued as rs1217396894, COSV51941689; called by muse, mutect2, varscan2
- IL1B | c.12A>G p.V4= | Silent (SNP) | VAF 47/111 reads (42%) | catalogued as COSV99641958; called by muse, mutect2, varscan2
- NUMA1 | c.5250C>T p.S1750= | Silent (SNP) | VAF 4/37 reads (11%) | catalogued as rs986769484, COSV99474869; called by muse, mutect2
- PC | c.1716C>T p.D572= | Silent (SNP) | VAF 8/104 reads (8%) | catalogued as rs577570512, COSV58921072; called by muse, mutect2
- TRIM26 | c.738G>A p.A246= | Silent (SNP) | VAF 35/76 reads (46%) | catalogued as rs765012397, COSV101359496; called by muse, mutect2, varscan2
- MDM4 | c.343+561G>C | Intron (SNP) | VAF 52/130 reads (40%) | catalogued as COSV100914571; called by muse, mutect2, varscan2
